Surgical pathology report (de-identified scan), TCGA case TCGA-FC-7708, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Asterand, specimen TCGA-FC-7708-01A (Primary Tumor).

[page 1 of 3]
Case ID	Gross Description	Microscopic Description
	Labeled prostate, left lymph nodes. The specimen consists of a 41 g prostate and seminal vesicles. The gland is 2.0 cm from base to apex, 5.1 cm transversely, and 3.5 cm from anterior to posterior. The seminal vesicles are up to 2.2 cm long. The left is inked black and the right blue. The apical margin is shaved and then sectioned perpendicularly. The base margin is similarly sectioned. The bases of the seminal vesicles are sampled. On sectioning, there is mild central nodular hyperplasia. The peripheral lobes are tan and spongy with a 2.1 x 2.0 cm indurated pale yellow focus within the left lobe near the mid-point. Separately within the container is a 3.7 x 2.6 x 1.0 cm fragment of lobulated tan fibroadipose tissue. Examination reveals 4 possible lymph nodes ranging from 0.3 to 1.5	Sections of the prostate gland show extensive adenocarcinoma with a Gleason pattern of $4 + 3 = 7$. Tumor is noted both in the left and right lobes with the quantity of tumor in the left lobe far greater than that in the right lobe. There is extracapsular extension noted. Tumor extends to the right and left base excision margins. The peripheral and apical margins excision margins are free of tumor. Perineural invasion is present. Tumor does not extend into the seminal vesicles. No angiolymphatic invasion is appreciated. There is background high grade prostatic intraepithelial neoplasia and glandular and stromal hypertrophy. Sections of the 4 lymph nodes show no evidence of metastatic tumor.

[page 2 of 3]
Diagnosis Details	Comments	Formatted Path Report
PROSTATECTOMY CHECKLIST 1) Tumor quantitation: a) Bilateral. b) Largest measurable focus of tumor: 2.1 x 2.0 cm. 2) Surgical margins: a) Bladder neck margin: Positive. b) Distal apical urethral margin: Negative. c) Peripheral margins: Negative. 3) Extraprostatic extension: Yes, established. 4) Seminal vesicles involved by tumor: No. 5) Angiolymphatic invasion: Absent. 6) Gleason score: 4 + 3 = 7. 7) TNM: T3a N0 Mx.		PROSTATE TISSUE CHECKLIST Specimen type: Robot assisted radical retropubic prostatectomy Tumor size: 2.1 x 2 cm Histologic type: Adenocarcinoma Gleason's score: 4 + 3 = 7/10 Focality: Multiple Laterality: Bilateral Extraprostatic extension: Present Lymph nodes: 0/4 positive for metastasis (Left pelvic 0/4) Lymphatic invasion: Absent Venous invasion: Absent Seminal vesicle invasion: Absent Margins: Involved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

ID

[page 3 of 3]
Lateralit y	Date of procurement
Bilateral	

Source: NCI Genomic Data Commons file ecd080a6-e436-4f6f-801f-612bf008347d (TCGA-FC-7708.DA17EDDC-BE95-4387-9C6A-FA647F33CEB7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).